Somatic mutation profile of tumor specimen TCGA-MQ-A4LM-01A (aliquot TCGA-MQ-A4LM-01A-11D-A34C-32) from TCGA case TCGA-MQ-A4LM, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 67.6 years (24,704 days).
Specimen TCGA-MQ-A4LM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68a0f564-7173-4752-a759-88ca570e9970.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MQ-A4LM-10B (Blood Derived Normal), aliquot TCGA-MQ-A4LM-10B-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a661583e-193d-4f79-be66-6684848d7528

The open-access MAF lists 38 somatic variants for this specimen: 26 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 11, Splice Site 2, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF2 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as rs74315503, CM941105, COSV58519919, COSV58524020; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARHGEF40 | c.3445G>C p.A1149P | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.587); catalogued as COSV53879288; called by muse, mutect2
- LAMA5 | c.10121G>C p.S3374T | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1220729564; called by muse, mutect2, varscan2
- SERPINE3 | c.373C>G p.P125A | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV99065968; called by muse, mutect2, varscan2
- TRIM31 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.124); catalogued as rs761288235; called by muse, mutect2, varscan2
- TRIP10 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs375676701, COSV57570946; called by muse, mutect2
- ZNF99 | c.1943C>T p.P648L | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs764617324; called by muse, mutect2, varscan2
- AFF1 | c.2249C>T p.S750L | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- APAF1 | c.1267_1268del p.L423Ffs*4 (on ENST00000551964 / NM_181861.2; = p.L412Ffs*4 on NM_001160.3) | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | called by pindel, varscan2
- CR1 | c.3734A>T p.D1245V | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DACH1 | c.1879G>C p.G627R (on ENST00000619232 / NM_001366712.1; = p.G373R on NM_004392.6) | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GNG7 | c.148G>C p.V50L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GTF2IRD2 | c.2302A>T p.I768F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.255); called by mutect2, varscan2
- HDLBP | c.1002dup p.D335Rfs*5 | Frame Shift Ins (INS) | VAF 11/78 reads (14%) | called by mutect2, pindel, varscan2
- HSPA1A | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFIH1 | c.1398G>T p.L466F | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.506); called by mutect2, varscan2
- ITPKB | c.2451+1G>T p.X817_splice | Splice Site (SNP) | VAF 7/53 reads (13%) | called by muse, varscan2
- LATS2 | c.1621G>T p.E541* | Nonsense Mutation (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- MRPS30 | c.338T>G p.V113G | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OR1J1 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PAX5 | c.1100-2A>C p.X367_splice | Splice Site (SNP) | VAF 6/67 reads (9%) | called by muse, mutect2
- PHRF1 | c.4313T>G p.M1438R (on ENST00000264555 / NM_001286581.2; = p.M1437R on NM_020901.4) | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGK1 | c.335G>A p.R112K | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SNRNP70 | c.1073A>G p.H358R | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated, low confidence (0.37); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- XBP1 | c.402A>T p.R134S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFC3H1 | c.698_705del p.K233Tfs*9 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | called by mutect2, pindel, varscan2
- CDCP2 | c.1170G>A p.Q390= | Silent (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- DCN | c.756G>A p.L252= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV50007101; called by muse, mutect2, varscan2
- DMRT3 | c.1269C>T p.P423= | Silent (SNP) | VAF 22/172 reads (13%) | catalogued as rs771880374, COSV99505845; called by muse, mutect2, varscan2
- MCUR1 | c.132G>C p.A44= | Silent (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- MRPS30 | c.339G>T p.V113= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs1351917015; called by muse, mutect2, varscan2
- PCDHB10 | c.969C>T p.D323= | Silent (SNP) | VAF 29/175 reads (17%) | catalogued as rs199921937; called by muse, mutect2, varscan2
- RUSC1 | c.1737G>A p.L579= (on ENST00000368352 / NM_001105203.2; = p.L110= on NM_014328.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 22/117 reads (19%) | called by muse, mutect2, varscan2
- SLC25A21 | c.159T>C p.Y53= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs185154903; called by muse, mutect2, varscan2
- SNRNP200 | c.4464G>T p.V1488= | Silent (SNP) | VAF 22/114 reads (19%) | called by muse, mutect2, varscan2
- XRN1 | c.510C>T p.G170= | Silent (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- ZNF536 | c.3738G>A p.A1246= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs763122092, COSV62817654; called by muse, mutect2, varscan2
- FAM169B | n.563C>T | RNA (SNP) | VAF 12/80 reads (15%) | catalogued as rs1403174326; called by muse, mutect2, varscan2
